Gene-level copy-number profile of tumor specimen TCGA-AA-A01R-01A from TCGA case TCGA-AA-A01R, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage III; Age at diagnosis: 47.3 years (17,289 days).
Specimen TCGA-AA-A01R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.34fd7e91-a4da-43d7-ba49-7702e4f46e54.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A01R-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d9b92bc2-9229-4bd7-874a-d5151f979121

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,861; copy number 2: 52,320; copy number 3: 3,538; copy number 4: 760; copy number 5: 264; copy number 6: 45; copy number 8: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A01R-01A-21D-A080-01): tumor purity 0.63, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 340 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:167,306,910–170,372,311, 43 genes, copy number 6–8: AC079349.1, RN7SL776P, PHBP14, RN7SKP188, AC105148.1, AC116634.1, ANXA10, AC068989.1, DDX60, DDX60L, AC079926.1, PALLD, BTF3L4P4, PALLD-AS1, RNU6-1336P, RPL9P16, AC080188.1, AC080188.2, CBR4, RNU6-853P, RNY4P17, AC021151.1, SH3RF1, RPL6P12, AC096741.1, NEK1, AC084724.1, CLCN3, HPF1, PTGES3P3, AC079768.1, AC079768.3, AC079768.4, LINC02275, AC079768.2, AC084866.2, AC084866.1, MFAP3L, AADAT, APOBEC3AP1, AC069306.1, LINC01612, LINC02512.
- chr6:16,761,138–17,293,871, 8 genes, copy number 5: ATXN1-AS1, AL137003.1, AL133405.2, AL133405.1, AL138740.1, STMND1, AL136305.1, RBM24.
- chr6:18,155,329–28,732,904, 289 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 480. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
